FM case AD11632 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026).
https://portal.gdc.cancer.gov/cases/35b7f500-ea27-434d-9653-db6cf8ac80a6

Male, 62.6 years: diagnosis not reported by GDC; metastasis biopsied or resected from the testis. Tumor nuclei on the sequenced sample's slide: 80% (pathologist estimate recorded by GDC). Sample type: Metastatic.
